Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJ3, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJ3-TTP2-A (Primary Tumor).

[page 1 of 2]
CDDP-YP-ABJ3-01-PR

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: (L) lung, upper lobe C34.1

ICD-10

C34.12

hw
2/9/16

- Material:** A) Left lung, upper lobe, removal
B) Left lung, lower lobar hilus neoformation, removal
C) Left lobar hilus lymph node, removal
D) Left pulmonary hilus lymph node (station 10L), removal
E) Right lung, upper lobe neoformation, removal
F) Right lung, u

Macro Description: A) Pulmonary lobe 21x11x3 cm, the visceral pleura is focally opaque and, when cut, retracted in correspondence to a 2.2 cm main axis greyish white neoformation with irregular margins, 6 cm from the bronchial resection. Remaining parenchyma looks congeste

Micro Description: A) Poorly differentiated pulmonary adenocarcinoma (G3), necrotic.

No evidence of neoplastic peritumoral angioinvasiveness.

Visceral pleura and margins of surgical bronchial resection free of neoplasia.

Pulmonary parenchyma emphysema around the lesion.

Virtual Microscope: Large cell CA

Real Microscope: Large cell carcinoma Additional notes: No NL, diff dx: adenoca, solid SQCA, poorly diff. Could not tell due to poor fixation

Slide Quality: 2- poorly fixed

Stage: G3

cT	cN	cM	cStage	cGrading
1	0	0	IA	X

pT	pN	pM	pStage	pGrading
1	0	1	IV	3

[page 2 of 2]
Report 2:
Report Date 2:

Material 2:

Macro Description 2:

Micro Description 2:

Notes: End Report and Date missing (report printed from computer).

ICDO Code: 81403

ICDO Description: Adenocarcinoma, NOS

Status: OK

Source: NCI Genomic Data Commons file c9d88941-8580-4624-981e-552784344d8a (CDDP-ABJ3-TTP2.62D1E85B-4BB0-4221-BDF6-57B9D5BCF0AD.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).